Somatic mutation profile of tumor specimen HTMCP-03-06-02123-01A (aliquot HTMCP-03-06-02123-01A-01D-5099) from CGCI case HTMCP-03-06-02123, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G3; Age at diagnosis: 59.7 years (21,792 days).
Specimen HTMCP-03-06-02123-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9256dbb0-fe9b-43ad-8be9-b1a54edcd4fc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02123-10A (Blood Derived Normal), aliquot HTMCP-03-06-02123-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2da30e6b-577a-4564-ae44-50253b31d8e1

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Nonsense Mutation 2, Intron 2, Splice Site 2, 3'UTR 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3823C>T p.R1275* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | hotspot (GDC flag); catalogued as rs543620241, COSV66557562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRS3 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 102/261 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1175523647, COSV65711169; called by muse, mutect2, varscan2
- COL25A1 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771718659, COSV67649474; called by muse, mutect2, varscan2
- CRB1 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 104/192 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.037); catalogued as rs146120995; called by muse, mutect2, varscan2
- DMBT1 | c.6025+1G>A p.X2009_splice (on ENST00000338354 / NM_001377530.1; = p.X1252_splice on NM_004406.3) | Splice Site (SNP) | VAF 67/152 reads (44%) | catalogued as rs878983340; called by muse, mutect2, varscan2
- DMD | c.7946G>A p.R2649Q | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.335); catalogued as COSV58919615; called by muse, mutect2
- ICE1 | c.6520+1G>A p.X2174_splice | Splice Site (SNP) | VAF 23/52 reads (44%) | catalogued as rs1219923105; called by muse, mutect2, varscan2
- MSR1 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs1162889692; called by muse, mutect2, varscan2
- NIPBL | c.7350G>A p.M2450I | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.262); catalogued as COSV56942566; called by muse, mutect2, varscan2
- PAN3 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs775770672, COSV66707094; called by muse, mutect2, varscan2
- PCDH10 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1338502775, COSV52104594; called by muse, mutect2, varscan2
- PCDHGA2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs149474643; called by muse, mutect2, varscan2
- PLD3 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs62107638, COSV62924381; called by muse, mutect2, varscan2
- TFDP1 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.057); catalogued as rs4150823; called by muse, mutect2, varscan2
- TTN | c.25110G>T p.K8370N (on ENST00000591111; = p.K7443N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/115 reads (40%) | PolyPhen benign (0.141); catalogued as COSV59899522; called by muse, mutect2, varscan2
- UNC80 | c.8819G>A p.R2940H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs371059292; called by muse, mutect2, varscan2
- WWC1 | c.1643C>G p.S548C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV54658396; called by muse, mutect2, varscan2
- ZMYM3 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1376678421, COSV100078329; called by muse, mutect2, varscan2
- ADAMTS17 | c.2866G>T p.D956Y | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH17 | c.11208T>A p.F3736L | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- FRMPD4 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- GTF3C1 | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- HUWE1 | c.12271_12297del p.Y4091_C4099del | In Frame Del (DEL) | VAF 66/203 reads (33%) | called by mutect2, pindel, varscan2
- POLK | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PRR14L | c.5948G>A p.G1983D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RARS2 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUNX1 | c.860_861del p.S287Cfs*285 (on ENST00000344691 / NM_001001890.3; = p.S314Cfs*285 on NM_001754.5) | Frame Shift Del (DEL) | VAF 83/144 reads (58%) | called by pindel, varscan2
- TTN | c.50051C>A p.P16684Q (on ENST00000591111; = p.P9260Q on NM_003319.4) | Missense Mutation (SNP) | VAF 69/167 reads (41%) | PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- VPS13D | c.443T>A p.I148N | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ZBBX | c.1615A>C p.K539Q | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZEB1 | c.1508G>T p.C503F | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CHD3 | c.4377C>T p.F1459= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1306491118; called by muse, mutect2, varscan2
- DYNC1LI1 | c.642G>A p.A214= | Silent (SNP) | VAF 72/246 reads (29%) | catalogued as rs371219514; called by muse, mutect2, varscan2
- INTS6L | c.543C>T p.T181= | Silent (SNP) | VAF 87/227 reads (38%) | catalogued as rs142715871; called by muse, mutect2, varscan2
- MALRD1 | c.6261T>C p.T2087= | Silent (SNP) | VAF 67/169 reads (40%) | called by muse, mutect2, varscan2
- MLH3 | c.2778G>A p.K926= | Silent (SNP) | VAF 76/174 reads (44%) | called by muse, mutect2, varscan2
- PAX1 | c.849G>A p.P283= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV68272278; called by muse, mutect2, varscan2
- PCDHA3 | c.735G>A p.T245= | Silent (SNP) | VAF 83/194 reads (43%) | catalogued as rs782471663, COSV65364891; called by muse, mutect2, varscan2
- PKHD1 | c.2034G>A p.P678= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs769144028; called by muse, mutect2, varscan2
- PLEC | c.9630C>T p.S3210= (on ENST00000322810 / NM_201380.4; = p.S3100= on NM_000445.5) | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs373397279; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RYR2 | c.9627G>A p.P3209= | Silent (SNP) | VAF 82/147 reads (56%) | catalogued as rs377730320; called by muse, mutect2, varscan2
- RYR3 | c.6639C>T p.N2213= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs1336776331, COSV63109786; called by muse, mutect2, varscan2
- TMC4 | c.1944C>T p.F648= (on ENST00000617472 / NM_001145303.3; = p.F642= on NM_144686.4) | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV55828791; called by muse, mutect2, varscan2
- WDR17 | c.2946C>T p.R982= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as rs146440894; called by muse, mutect2, varscan2
- ADAMTS2 | c.1629+954G>A | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as COSV51101022; called by muse, mutect2
- CNOT6L | c.5+150_5+170del | Intron (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- ZNF827 | c.*131A>T | 3'UTR (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2, varscan2
